Somatic mutation profile of tumor specimen TCGA-KU-A6H7-06A (aliquot TCGA-KU-A6H7-06A-21D-A31L-08) from TCGA case TCGA-KU-A6H7, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 55.6 years (20,314 days).
Specimen TCGA-KU-A6H7-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02193ee5-9e2e-4b8a-9d2f-f5f64a62bd00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KU-A6H7-10A (Blood Derived Normal), aliquot TCGA-KU-A6H7-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f6760db-c077-4cbd-ac95-8828d3974257

The open-access MAF lists 80 somatic variants for this specimen: 58 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 19, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 2, RNA 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYLD | c.1112C>A p.S371* | Nonsense Mutation (SNP) | VAF 25/36 reads (69%) | catalogued as rs886040872, CM001113, COSV61094720; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100933104; called by muse, mutect2, varscan2
- AP4E1 | c.3364C>T p.L1122F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1260930330, COSV99956617; called by muse, mutect2, varscan2
- APBA1 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV99596028; called by muse, mutect2, varscan2
- ARID4A | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV100794161; called by muse, mutect2, varscan2
- AURKC | c.720G>C p.E240D (on ENST00000302804 / NM_001015878.2; = p.E206D on NM_003160.3) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100248847; called by muse, mutect2, varscan2
- CACNA1H | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs772154386, COSV61988665; called by muse, mutect2, varscan2
- CAPZA2 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as COSV100753904, COSV63266205; called by muse, mutect2, varscan2
- CCT8L2 | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as COSV63461767, COSV63463898; called by muse, mutect2, varscan2
- CIAO1 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV51498278; called by muse, mutect2, varscan2
- DCHS1 | c.1055T>C p.V352A | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100202011; called by muse, mutect2, varscan2
- DPH3 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as COSV99550887; called by muse, mutect2, varscan2
- EFHC2 | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs928441960, COSV101375471; called by muse, mutect2, varscan2
- EIF5B | c.2870C>T p.P957L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV99177229; called by muse, mutect2, varscan2
- EXTL3 | c.2646C>G p.F882L | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV99593986; called by muse, mutect2, varscan2
- FCGR2A | c.674C>T p.A225V (on ENST00000271450 / NM_001136219.3; = p.A224V on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs199502630, COSV54839792; called by muse, mutect2, varscan2
- GALNS | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99243163; called by muse, mutect2, varscan2
- GPR35 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as rs747391123, COSV60577136; called by muse, mutect2, varscan2
- HNRNPD | c.351T>A p.F117L | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0.359); catalogued as COSV100002848; called by muse, mutect2, varscan2
- ISY1 | c.541+1G>T p.X181_splice | Splice Site (SNP) | VAF 21/80 reads (26%) | catalogued as COSV99860730, COSV99860886; called by muse, mutect2, varscan2
- ITGAV | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.619); catalogued as COSV53710063; called by muse, mutect2, varscan2
- KCNH7 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs776350714, COSV59783186; called by muse, mutect2, varscan2
- KCNK1 | c.896T>G p.L299R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV100785692; called by muse, mutect2, varscan2
- KCNQ4 | c.792C>G p.N264K | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100714307; called by muse, mutect2, varscan2
- LRP5 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV99591792; called by muse, mutect2, varscan2
- LRRK2 | c.4372G>A p.D1458N | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100109849; called by muse, mutect2, varscan2
- LUZP4 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as rs782627471, COSV100904848; called by muse, mutect2, varscan2
- MIA3 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100719406; called by muse, mutect2, varscan2
- MTCL1 | c.5680-1G>A p.X1894_splice (on ENST00000306329 / NM_001378206.1; = p.X1575_splice on NM_015210.4) | Splice Site (SNP) | VAF 26/76 reads (34%) | catalogued as COSV100094176; called by muse, mutect2, varscan2
- MYH6 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100676556; called by muse, mutect2, varscan2
- MYPN | c.1038C>G p.I346M | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100589929; called by muse, mutect2, varscan2
- NPTX2 | c.930C>A p.H310Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99674882; called by muse, mutect2, varscan2
- NXF1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.156); catalogued as COSV99586005; called by muse, mutect2, varscan2
- OR4D5 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as rs564572858, COSV58305578; called by muse, mutect2, varscan2
- PBRM1 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 31/48 reads (65%) | catalogued as COSV56263765, COSV99968670; called by muse, mutect2, varscan2
- PCDHB4 | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as COSV99522050; called by muse, mutect2, varscan2
- PCLO | c.5503G>C p.D1835H | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100430721; called by muse, varscan2
- PCLO | c.5386G>C p.E1796Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100430728, COSV61642955; called by muse, varscan2
- PITPNM2 | c.3853G>A p.D1285N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs758566561, COSV99758858; called by muse, varscan2
- PPP1CB | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99941833; called by muse, mutect2, varscan2
- PPP4R4 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV100175702; called by muse, mutect2, varscan2
- RAI2 | c.1510A>C p.K504Q | Missense Mutation (SNP) | VAF 212/559 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100518262; called by muse, mutect2, varscan2
- SLC32A1 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.274); catalogued as COSV99461966; called by muse, mutect2
- SPEN | c.2645G>C p.R882P | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV101005213, COSV65366999; called by muse, mutect2, varscan2
- SYCP2 | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100698240; called by muse, mutect2, varscan2
- TFIP11 | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99314593; called by muse, mutect2, varscan2
- TIAM2 | c.3082G>C p.D1028H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as COSV100018639; called by muse, mutect2, varscan2
- TNIP1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs867041708, COSV100161309, COSV100161318; called by muse, mutect2, varscan2
- TRIM36 | c.1210A>G p.T404A | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as rs1006282540, COSV99142384; called by muse, mutect2, varscan2
- TRRAP | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62842499; called by muse, mutect2, varscan2
- TRRAP | c.7028G>A p.R2343Q (on ENST00000359863 / NM_001244580.1; = p.R2325Q on NM_003496.3) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1197218649, COSV100722335; called by muse, mutect2, varscan2
- ZMYM3 | c.2684C>T p.P895L | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100077844; called by muse, mutect2, varscan2
- ZNF160 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.262); catalogued as COSV100762327; called by muse, mutect2, varscan2
- ZNF235 | c.1093C>A p.H365N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99349437; called by mutect2, varscan2
- ZNF750 | c.102C>A p.C34* | Nonsense Mutation (SNP) | VAF 34/47 reads (72%) | catalogued as COSV99489722, COSV99489740; called by muse, mutect2, varscan2
- ZNF862 | c.1666G>C p.E556Q | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV99783476; called by muse, mutect2, varscan2
- CIAO1 | c.344del p.P115Hfs*51 | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | called by mutect2, pindel, varscan2
- RAB2A | c.629del p.G210Afs*10 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- AFAP1L2 | c.1860G>A p.Q620= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as COSV100412506; called by muse, mutect2, varscan2
- ARHGAP9 | c.1482C>G p.L494= (on ENST00000393797 / NM_001319850.2; = p.L475= on NM_032496.4) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV57363855, COSV99954097; called by muse, mutect2, varscan2
- ATP2B3 | c.1452C>T p.T484= | Silent (SNP) | VAF 60/193 reads (31%) | catalogued as rs782621008, COSV99684041; called by muse, mutect2, varscan2
- C1orf109 | c.87G>A p.Q29= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV59240499; called by muse, mutect2, varscan2
- CDC42BPG | c.1576C>T p.L526= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100712058; called by mutect2, varscan2
- CRB1 | c.2805C>T p.H935= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as rs767706271, COSV66332011, COSV66333152; called by muse, mutect2, varscan2
- ITGB4 | c.4797C>T p.R1599= | Silent (SNP) | VAF 57/171 reads (33%) | catalogued as rs530315339, COSV99563984, COSV99565202; called by muse, mutect2, varscan2
- KIF4B | c.411A>G p.K137= | Silent (SNP) | VAF 52/105 reads (50%) | catalogued as COSV101469230; called by muse, mutect2, varscan2
- LGR6 | c.2283C>T p.G761= (on ENST00000367278 / NM_001017403.1; = p.G709= on NM_021636.3) | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs984296309, COSV55164673; called by muse, mutect2, varscan2
- MET | c.1062C>T p.A354= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs755166920, COSV100577159; ClinVar: likely benign; called by muse, mutect2, varscan2
- NDUFV1 | c.1110C>A p.L370= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV100508399; called by muse, varscan2
- PAK5 | c.1431G>A p.V477= | Silent (SNP) | VAF 54/142 reads (38%) | catalogued as COSV62031915; called by muse, varscan2
- PITX1 | c.411C>T p.F137= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as COSV99530601; called by muse, mutect2, varscan2
- PPP1R16B | c.741C>T p.L247= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV55382695; called by muse, mutect2
- PTX3 | c.75C>T p.L25= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV55821208, COSV99904864; called by muse, mutect2, varscan2
- SNX25 | c.12T>G p.A4= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99252823; called by muse, mutect2
- TNRC6A | c.4524C>T p.F1508= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV100169438; called by muse, mutect2, varscan2
- UBE2E2 | c.477C>T p.S159= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV100232762; called by muse, mutect2, varscan2
- UNC45B | c.1335C>T p.L445= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV99268661; called by muse, mutect2, varscan2
- CNOT3 | c.2037+229G>T | Intron (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99651819; called by muse, mutect2, varscan2
- MIR1207 | n.37G>A | RNA (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- MRPS17P9 | n.316C>T | RNA (SNP) | VAF 22/52 reads (42%) | called by muse, varscan2
